Surgical pathology report (de-identified scan), TCGA case TCGA-ZB-A96F, project TCGA-THYM (Thymoma), tissue source site Thoraxklinik, specimen TCGA-ZB-A96F-01A (Primary Tumor).

Name:

Identifier:

Unique Patient #:

Tumor Type : Thymoma

Pathology Report-Summary:

Material:

tumor: diameter 2.0 cm

Diagnosis:

Type A/BThymoma

pT1

Masaoka: I

ICD O-3
Thymoma, type AB malignant
8582/3
Site Anterior mediastinum
C38.1
Q4 4/7/14

Immunohistochemistry

epithelial cells positive for: CK5/6
medium to strong membrane staining for EGFR

epithelial cells negative for: CD1a, CD5, CD20, CD99, CD117
Ki-67: 10-20%

CD1a, CD5, CD99-positive immature T-lymphocytes, partially also positive for CD5
sparsely CD20-positive lymphocytes
Ki-67: 60-80%

Source: NCI Genomic Data Commons file 10cac0bf-b0d7-45ef-8f76-43a062a2fbfc (TCGA-ZB-A96F.3EC1FFEF-2852-4DBB-BCCB-9946B8645647.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).